Somatic mutation profile of tumor specimen TCGA-JW-A5VG-01A (aliquot TCGA-JW-A5VG-01A-11D-A28B-09) from TCGA case TCGA-JW-A5VG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 35.9 years (13,109 days).
Specimen TCGA-JW-A5VG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 517783e8-72f7-4eee-9009-118354cdfc69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-A5VG-10A (Blood Derived Normal), aliquot TCGA-JW-A5VG-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8528707-260c-4db6-87c7-c18bf655b05c

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 2, Intron 1, Splice Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481340390, COSV57001176, COSV57001879; called by muse, mutect2, varscan2
- ALMS1 | c.4084G>A p.V1362I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as rs534858351, COSV52523917; called by muse, mutect2, varscan2
- ATM | c.5755C>T p.Q1919* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53780171; called by muse, mutect2, varscan2
- BCHE | c.935C>G p.T312S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52255898, COSV52263314; called by muse, mutect2, varscan2
- CAMSAP1 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV56722616; called by muse, mutect2, varscan2
- DCAF4L1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as rs143365042; called by muse, mutect2, varscan2
- DUOXA1 | c.128C>G p.P43R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50995098; called by muse, mutect2, varscan2
- E2F8 | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as rs760623568, COSV51466560; called by muse, mutect2, varscan2
- GTF3C1 | c.2878C>T p.R960C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62245608; called by muse, mutect2, varscan2
- HRNR | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as rs147754674, COSV64255569; called by muse, mutect2, varscan2
- KCNJ6 | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV55711643, COSV55724768; called by muse, mutect2, varscan2
- LAMB1 | c.3928A>G p.K1310E | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV99740307; called by muse, mutect2, varscan2
- MRPS31 | c.652G>C p.V218L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV100062128; called by muse, mutect2
- NCF2 | c.556A>T p.N186Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV62316966; called by muse, mutect2, varscan2
- OVOL2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1419305548, COSV53859667, COSV53861786; called by mutect2, varscan2
- PLCB1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.213); catalogued as COSV62071586; called by muse, mutect2, varscan2
- POLR2B | c.1235T>G p.L412R | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.431); catalogued as COSV58903197; called by muse, mutect2, varscan2
- PTPRD | c.2270G>A p.G757D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV61987563; called by muse, mutect2, varscan2
- RALGAPA1 | c.2237C>A p.A746E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV99354018; called by muse, mutect2
- SH3BP4 | c.445A>C p.K149Q | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60646993; called by muse, mutect2, varscan2
- SIRPA | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV61537890; called by muse, mutect2, varscan2
- SPAST | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs202152835, CM130168, COSV59515437; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TDRD1 | c.2212+2T>C p.X738_splice | Splice Site (SNP) | VAF 25/54 reads (46%) | catalogued as COSV52597293; called by muse, mutect2, varscan2
- TRIL | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59868206; called by muse, mutect2, varscan2
- TRO | c.1451A>G p.E484G | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51508997; called by muse, mutect2, varscan2
- HERC1 | c.6249_6251del p.R2083_G2084delinsS | In Frame Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- BRINP1 | c.894C>T p.A298= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs376177879; called by muse, mutect2, varscan2
- FANCC | c.201T>C p.I67= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as COSV56668301; called by muse, mutect2, varscan2
- SLC12A7 | c.1554C>T p.A518= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs745653159, COSV53755859; called by muse, mutect2, varscan2
- ZNF521 | c.2289C>T p.N763= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs759243243, COSV64132832; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824209 G>A | 5'Flank (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- KAT6A | c.1483-1812G>A | Intron (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
